Somatic mutation profile of tumor specimen 0DX7FX from CCDI case PBCRCF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 10.4 years (3,812 days).
Specimen 0DX7FX: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26bf328d-e707-4403-8672-6512bc02505e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f7ea2d5-1f0f-4739-847c-2c03a145c278

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 4, 3'UTR 1, Translation Start Site 1, Splice Region 1, Nonsense Mutation 1, RNA 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 861/874 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- CARD6 | c.2400G>T p.M800I | Missense Mutation (SNP) | VAF 115/570 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54564513; called by muse, mutect2, varscan2
- ECI1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 67/749 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1474825185; called by muse, mutect2
- MAGEB6 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 43/921 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.586); catalogued as rs187176082, COSV66872108; called by muse, mutect2
- MIA2 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 305/666 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as rs1272360490; called by muse, mutect2, varscan2
- MTOR | c.4171C>G p.R1391G | Missense Mutation (SNP) | VAF 28/824 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100815589, COSV63874955; called by muse, mutect2
- SCN2A | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769825203, COSV51847689, COSV51849419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A6 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 217/484 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs138163519; called by muse, mutect2, varscan2
- ABCA12 | c.1794G>T p.Q598H (on ENST00000272895 / NM_173076.3; = p.Q280H on NM_015657.3) | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP6 | c.2389del p.A797Lfs*45 (on ENST00000337414 / NM_013427.3; = p.A594Lfs*45 on NM_013423.3) | Frame Shift Del (DEL) | VAF 264/621 reads (43%) | called by mutect2, pindel, varscan2
- CCNB1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 94/530 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK13 | c.438C>G p.Y146* | Nonsense Mutation (SNP) | VAF 228/516 reads (44%) | called by muse, mutect2, varscan2
- CNTN4 | c.1427C>A p.T476N | Missense Mutation (SNP) | VAF 193/421 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCP1B | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 214/463 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DMD | c.3459G>T p.K1153N | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- FERMT1 | c.450_452dup p.K152dup | In Frame Ins (INS) | VAF 137/303 reads (45%) | called by mutect2, varscan2
- LEFTY1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 253/527 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MOSMO | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 249/510 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SLFN14 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 79/757 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); called by muse, mutect2
- UHRF1BP1 | c.840G>A p.Q280= | Splice Region (SNP) | VAF 26/521 reads (5%) | called by muse, mutect2
- WNK3 | c.3328A>G p.I1110V | Missense Mutation (SNP) | VAF 30/852 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- YIPF7 | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 304/614 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZEB2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 93/451 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF674 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 240/493 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ACBD7 | c.153A>G p.L51= | Silent (SNP) | VAF 28/504 reads (6%) | catalogued as rs17852678; called by muse, mutect2
- DCX | c.576G>A p.R192= | Silent (SNP) | VAF 34/625 reads (5%) | called by muse, mutect2
- HSD3B1 | c.273C>A p.V91= | Silent (SNP) | VAF 204/624 reads (33%) | catalogued as rs587610114; called by muse, mutect2
- IQSEC1 | c.435T>C p.F145= | Silent (SNP) | VAF 232/439 reads (53%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.66C>T p.N22= | Silent (SNP) | VAF 43/427 reads (10%) | called by muse, mutect2, varscan2
- PIGN | c.972T>C p.I324= | Silent (SNP) | VAF 53/343 reads (15%) | called by muse, mutect2, varscan2
- SEMA4G | c.2316G>A p.P772= (on ENST00000370250; = p.P777= on NM_017893.3) | Silent (SNP) | VAF 16/566 reads (3%) | catalogued as rs1199749295; called by muse, mutect2
- SSBP4 | c.483G>A p.R161= | Silent (SNP) | VAF 78/998 reads (8%) | called by muse, mutect2
- DENND1C | c.448-17T>C | Intron (SNP) | VAF 162/578 reads (28%) | called by muse, mutect2
- FGFR1OP2 | c.510+21A>T | Intron (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- MED13L | c.6226-48A>G | Intron (SNP) | VAF 7/198 reads (4%) | catalogued as rs1160377994; called by muse, mutect2
- OR52Z1 | n.637G>C | RNA (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- SP140L | c.1313+59G>A | Intron (SNP) | VAF 66/155 reads (43%) | catalogued as rs1054560156; called by muse, mutect2, varscan2
- TEX51 | c.*27G>T | 3'UTR (SNP) | VAF 151/333 reads (45%) | catalogued as rs1486021055; called by muse, mutect2, varscan2
